CCDI case PBCDLM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/1c6c3314-f2f1-44e0-b070-01584723a5a6

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Infantile fibrosarcoma: ICD-O-3 morphology code: 8814/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 0.3 years (99 days).

Biospecimens (3 samples)
- Sample 0DPDHE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPDHN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPDIA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
